Somatic mutation profile of tumor specimen TCGA-IB-8127-01A (aliquot TCGA-IB-8127-01A-11D-2396-08) from TCGA case TCGA-IB-8127, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.3 years (21,676 days).
Specimen TCGA-IB-8127-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf048b76-137f-4e5f-8fcc-a2969d962e88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-8127-10A (Blood Derived Normal), aliquot TCGA-IB-8127-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c39930e8-bebc-4cac-86e5-9f53601503f3

The open-access MAF lists 43 somatic variants for this specimen: 25 protein-altering or splice-affecting, 18 silent.
By variant classification: Silent 18, Missense Mutation 18, Nonsense Mutation 4, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7268A>G p.E2423G | Missense Mutation (SNP) | VAF 146/302 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs121434221, COSV53769225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 50/159 reads (31%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 85/447 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 52/131 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.602+1G>A p.X201_splice | Splice Site (SNP) | VAF 77/340 reads (23%) | catalogued as rs794726827, CS032427, CS096271, COSV100321747, COSV57662425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 38/124 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BIRC7 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs748887501, COSV53900706, COSV99416544; called by muse, mutect2
- BTBD11 | c.2050G>A p.E684K (on ENST00000280758 / NM_001018072.2; = p.E221K on NM_001017523.2) | Missense Mutation (SNP) | VAF 89/646 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as rs147351765, COSV55025977; called by muse, mutect2, varscan2
- CACNA1B | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259261506, COSV53124713; called by muse, mutect2
- CEP85 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 70/495 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs756429210, COSV99431956; called by muse, mutect2, varscan2
- CNTNAP5 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 54/552 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756000668, COSV70498892; called by muse, mutect2, varscan2
- CPPED1 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV99902902; called by muse, mutect2, varscan2
- DHX15 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.114); catalogued as COSV61029072; called by muse, mutect2, varscan2
- HMCN1 | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 186/720 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143393655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD8 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 97/686 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs765990631, COSV63586384; called by muse, mutect2, varscan2
- KIAA0586 | c.1996G>T p.V666L (on ENST00000619416 / NM_001244190.2; = p.V605L on NM_014749.5) | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV99707749; called by muse, mutect2, varscan2
- LRP1B | c.6718C>T p.R2240* | Nonsense Mutation (SNP) | VAF 177/735 reads (24%) | catalogued as COSV101254260; called by muse, mutect2, varscan2
- NOL4L | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 220/833 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758055534, COSV100675584; called by muse, mutect2, varscan2
- PCDH9 | c.3361G>T p.G1121* (on ENST00000377865 / NM_203487.3; = p.G1087* on NM_020403.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 47/239 reads (20%) | catalogued as COSV100119279; called by muse, mutect2, varscan2
- PPP1R3A | c.2420T>G p.L807* | Nonsense Mutation (SNP) | VAF 134/524 reads (26%) | catalogued as COSV99492302; called by muse, mutect2, varscan2
- RNF43 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 168/546 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV101348356, COSV101348511, COSV68457168; called by muse, mutect2, varscan2
- SERPINA7 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 623/1279 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.303); catalogued as COSV100568247, COSV59667170; called by muse, mutect2, varscan2
- ZNRF4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771572851, COSV55776932; called by muse, mutect2, varscan2
- MMS19 | c.2655del p.D886Mfs*2 | Frame Shift Del (DEL) | VAF 122/456 reads (27%) | called by mutect2, pindel, varscan2
- UNC50 | c.6dup p.P3Tfs*45 | Frame Shift Ins (INS) | VAF 468/2229 reads (21%) | called by mutect2, pindel, varscan2
- ACP6 | c.318C>T p.Y106= | Silent (SNP) | VAF 102/402 reads (25%) | catalogued as rs782815891, COSV65078248; called by muse, mutect2, varscan2
- ATP1A3 | c.2067C>T p.T689= (on ENST00000545399 / NM_001256214.2; = p.T676= on NM_152296.5) | Silent (SNP) | VAF 128/462 reads (28%) | catalogued as rs782556831, COSV57488358; called by muse, mutect2, varscan2
- CLEC4F | c.1581C>T p.I527= | Silent (SNP) | VAF 162/797 reads (20%) | catalogued as rs561064679, COSV99713624; called by muse, mutect2, varscan2
- EPHA8 | c.2238C>T p.A746= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs560800908, COSV51262399; called by muse, mutect2, varscan2
- F5 | c.3927G>A p.Q1309= | Silent (SNP) | VAF 513/2417 reads (21%) | catalogued as CD982637, COSV63120147; called by muse, mutect2, varscan2
- GABRD | c.984C>T p.Y328= | Silent (SNP) | VAF 38/320 reads (12%) | catalogued as rs759009305, COSV101059518; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXC10 | c.345C>T p.S115= | Silent (SNP) | VAF 94/447 reads (21%) | catalogued as rs751259175, COSV57725978; called by muse, mutect2, varscan2
- IGHE | c.702G>A p.S234= | Silent (SNP) | VAF 26/316 reads (8%) | catalogued as rs782705134; called by muse, mutect2
- IRF4 | c.966C>T p.D322= | Silent (SNP) | VAF 93/278 reads (33%) | catalogued as rs113364548, COSV101110773, COSV101110814; called by muse, mutect2, varscan2
- NRXN3 | c.1623G>A p.T541= (on ENST00000557594 / NM_001272020.2; = p.T965= on NM_004796.6) | Silent (SNP) | VAF 44/391 reads (11%) | catalogued as rs535295435, COSV55330208, COSV55335019; called by muse, mutect2, varscan2
- PCDHGA1 | c.2088G>A p.A696= | Silent (SNP) | VAF 164/1266 reads (13%) | catalogued as rs762914963, COSV100965943, COSV65295211; called by muse, mutect2, varscan2
- PCDHGA9 | c.1128C>T p.S376= | Silent (SNP) | VAF 101/324 reads (31%) | catalogued as rs369802030; called by muse, mutect2, varscan2
- SCN5A | c.2547C>T p.I849= | Silent (SNP) | VAF 63/546 reads (12%) | catalogued as CD078502, COSV61132548; called by muse, mutect2, varscan2
- SERINC2 | c.729C>T p.N243= (on ENST00000373709 / NM_178865.5; = p.N247= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 215/1329 reads (16%) | catalogued as rs782124569, COSV101036769; called by muse, mutect2, varscan2
- USP20 | c.2439G>A p.S813= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs781264175, COSV59619579; called by muse, varscan2
- VPS35L | c.975G>A p.G325= | Silent (SNP) | VAF 75/269 reads (28%) | catalogued as COSV99220078; called by muse, mutect2, varscan2
- VWA1 | c.663G>A p.T221= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs773287477, COSV100100623; called by muse, mutect2
- WNK2 | c.6828G>A p.P2276= | Silent (SNP) | VAF 68/251 reads (27%) | catalogued as rs369158903; called by muse, mutect2, varscan2
